Somatic mutation profile of tumor specimen MMRF_2832_1_BM_CD138pos (aliquot MMRF_2832_1_BM_CD138pos_T1_KHS5U_L16564) from MMRF case MMRF_2832, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2832_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb465635-3607-49c4-8467-5f3fe80d7603.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2832_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2832_1_PB_WBC_C2_KHS5U_L16611; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0792df2f-35a8-423c-92e3-3966eaa42935

The open-access MAF lists 100 somatic variants for this specimen: 32 protein-altering or splice-affecting, 17 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 25, Silent 17, Intron 15, 5'UTR 5, 5'Flank 3, RNA 2, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 116/377 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALS2 | c.4463C>T p.P1488L | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs748453218, COSV99969728; called by muse, mutect2, varscan2
- CNGB3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs141098074; called by muse, mutect2, varscan2
- CSMD3 | c.1495G>A p.G499R (on ENST00000297405 / NM_001363185.1; = p.G395R on NM_052900.3) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778693042, COSV52188195; called by muse, mutect2, varscan2
- FLNC | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs759075520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYB2 | c.1682C>A p.T561N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs368189394, COSV58583233; called by muse, mutect2, varscan2
- GALNT13 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759879455, COSV101221753, COSV67229712; called by muse, mutect2, varscan2
- GPR162 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781871717, COSV50596748; called by muse, mutect2, varscan2
- GRIA1 | c.2362G>A p.G788S | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs368111555; called by muse, mutect2, varscan2
- H2BC5 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 210/303 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV56804062; called by muse, mutect2, varscan2
- IGLV4-60 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs766466532, COSV66503710; called by muse, varscan2
- IQSEC3 | c.1049G>A p.R350Q (on ENST00000538872 / NM_001170738.2; = p.R47Q on NM_015232.1) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782640693; called by muse, mutect2, varscan2
- LANCL2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 79/251 reads (31%) | catalogued as rs760000850, COSV99635284; called by muse, mutect2, varscan2
- MAP3K14 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768000548, COSV60922931, COSV60923658; called by muse, mutect2, varscan2
- OR5J2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 152/244 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs771815905, COSV56622824; called by muse, mutect2, varscan2
- PLXNA4 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 117/161 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0.073); catalogued as rs146112863; called by muse, mutect2, varscan2
- ACTG2 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ATXN3 | c.65T>C p.L22S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- B3GNTL1 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTN3A1 | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FREM2 | c.6785A>T p.E2262V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR1E | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV1-51 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IGLV6-57 | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2
- KIAA1109 | c.14956A>C p.K4986Q | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KLHL14 | c.367A>T p.N123Y | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- L3HYPDH | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LRP6 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- NOC2L | c.1062dup p.I355Hfs*243 | Frame Shift Ins (INS) | VAF 56/167 reads (34%) | called by mutect2, pindel, varscan2
- NRXN1 | c.2092T>G p.Y698D | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SPACA6 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- SYN1 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- C11orf24 | c.619C>T p.L207= | Silent (SNP) | VAF 83/213 reads (39%) | catalogued as COSV100422783; called by muse, mutect2, varscan2
- C17orf99 | c.87C>T p.V29= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs1479673139; called by muse, mutect2, varscan2
- CAV1 | c.87C>T p.N29= | Silent (SNP) | VAF 69/115 reads (60%) | called by muse, mutect2, varscan2
- CDH17 | c.1665T>A p.L555= | Silent (SNP) | VAF 53/166 reads (32%) | called by muse, mutect2, varscan2
- CLCA1 | c.1533C>T p.T511= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1265964400, COSV52327999; called by muse, mutect2, varscan2
- FBN3 | c.264C>T p.R88= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs770235641; called by muse, mutect2, varscan2
- INTU | c.2823C>A p.T941= | Silent (SNP) | VAF 38/326 reads (12%) | catalogued as COSV100080805; called by muse, mutect2, varscan2
- KLK10 | c.708C>T p.D236= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs895207392; called by muse, mutect2, varscan2
- MYO5A | c.726T>C p.Y242= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs1396926100; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA5B | c.2370C>T p.G790= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs769028093; called by muse, mutect2, varscan2
- SI | c.585C>T p.A195= | Silent (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- SLC22A24 | c.306C>T p.N102= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs752763366; called by muse, mutect2, varscan2
- SLC35F4 | c.84A>G p.S28= | Silent (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2, varscan2
- TENM1 | c.6570T>A p.R2190= | Silent (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.1374T>C p.H458= | Silent (SNP) | VAF 127/202 reads (63%) | called by muse, mutect2, varscan2
- WDR33 | c.504G>A p.T168= | Silent (SNP) | VAF 66/111 reads (59%) | catalogued as rs767308190, COSV59249535; called by muse, mutect2, varscan2
- ZRANB3 | c.1749G>A p.S583= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs370277349; called by muse, mutect2, varscan2
- ABL1 | c.*447T>C | 3'UTR (SNP) | VAF 44/161 reads (27%) | called by muse, mutect2, varscan2
- ACTB | c.124-45_124-28del | Intron (DEL) | VAF 116/239 reads (49%) | called by mutect2, pindel, varscan2
- APOLD1 | c.*1285C>G | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.*1530T>C | 3'UTR (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- B3GLCT | c.*352A>C | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- C6orf223 | n.1239G>A | RNA (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- CAP2 | c.*81G>T | 3'UTR (SNP) | VAF 138/491 reads (28%) | catalogued as COSV100012492; called by muse, mutect2, varscan2
- CASP10 | c.1416-9400T>G | Intron (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CHI3L2 | c.*2+128G>A | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- CKMT1A | c.876+100G>A | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2
- CLDN1 | c.*2395del | 3'UTR (DEL) | VAF 15/67 reads (22%) | catalogued as rs1021749427; called by mutect2, pindel, varscan2
- FOXN2 | c.*3061G>A | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- HGS | c.-43G>A | 5'UTR (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- ITSN1 | c.*9616del | 3'UTR (DEL) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- LINC02448 | n.544A>G | RNA (SNP) | VAF 132/282 reads (47%) | catalogued as rs1413102265; called by muse, mutect2
- LRRN3 | c.-291G>T | 5'UTR (SNP) | VAF 44/69 reads (64%) | called by muse, mutect2, varscan2
- LYPD6 | c.218-4372C>A | Intron (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- MAP3K1 | c.*2365A>G | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- MIB1 | c.*1919C>A | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851135 G>A | 5'Flank (SNP) | VAF 78/160 reads (49%) | catalogued as rs767934823; called by muse, varscan2
- MIR5195 | chr14:106851312 T>G | 5'Flank (SNP) | VAF 62/140 reads (44%) | catalogued as rs1376536873; called by muse, varscan2
- MIR5195 | chr14:106851386 A>C | 5'Flank (SNP) | VAF 46/105 reads (44%) | called by muse, varscan2
- MKRN3 | c.*43G>A | 3'UTR (SNP) | VAF 402/629 reads (64%) | catalogued as rs748369571, COSV58810337; called by muse, mutect2, varscan2
- MPHOSPH9 | c.*2580A>G | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs185471046; called by muse, varscan2
- MPZL1 | c.*3368A>G | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- NSD1 | c.927+1149T>G | Intron (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
- OXR1 | c.224-61034G>A | Intron (SNP) | VAF 106/227 reads (47%) | called by muse, mutect2, varscan2
- PANK2 | chr20:3926188 A>T | 3'Flank (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- PARVA | c.798+37G>A | Intron (SNP) | VAF 76/230 reads (33%) | catalogued as rs778736977, COSV58513934; called by muse, mutect2, varscan2
- PDGFRA | c.*2638T>C | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- PFKFB2 | c.*1595T>G | 3'UTR (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- PHKA1 | c.*1896T>A | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- PLCB1 | c.*900G>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs563531029; called by mutect2, varscan2
- PPP2R3B | c.793-16G>A | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as COSV66814713; called by muse, varscan2
- PSMD14 | c.*293C>T | 3'UTR (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- PTPN2 | c.*65T>A | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- PTRH1 | c.-1064C>T | 5'UTR (SNP) | VAF 25/80 reads (31%) | catalogued as rs1248074295; called by muse, mutect2, varscan2
- RFX2 | c.1135-144G>A | Intron (SNP) | VAF 108/175 reads (62%) | catalogued as rs989744711; called by muse, mutect2, varscan2
- RGL1 | c.*139A>G | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- SLC41A3 | c.1367-265A>G | Intron (SNP) | VAF 74/115 reads (64%) | called by muse, mutect2, varscan2
- SLITRK4 | c.*118G>C | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- SRF | c.*1079G>C | 3'UTR (SNP) | VAF 55/87 reads (63%) | called by muse, mutect2, varscan2
- STMN4 | c.510+696C>T | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as rs1413347399, COSV56109024; called by muse, mutect2, varscan2
- STRBP | c.*439C>T | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- TMEM106B | c.*3270A>C | 3'UTR (SNP) | VAF 24/38 reads (63%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.-663-628G>A | Intron (SNP) | VAF 72/132 reads (55%) | called by muse, mutect2, varscan2
- TTN | c.44126-18C>T | Intron (SNP) | VAF 35/107 reads (33%) | catalogued as rs1382435221; called by muse, mutect2, varscan2
- UCP1 | c.-33C>A | 5'UTR (SNP) | VAF 65/105 reads (62%) | called by muse, mutect2, varscan2
- ZIC1 | c.-703C>T | 5'UTR (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- ZNF28 | c.*40A>G | 3'UTR (SNP) | VAF 64/358 reads (18%) | called by muse, varscan2
- ZNF749 | c.15+25C>G | Intron (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
